Gene-level copy-number profile of tumor specimen TARGET-10-PANGIF-09A from TARGET case TARGET-10-PANGIF, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.2 years (4,087 days).
Specimen TARGET-10-PANGIF-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.03bc29bf-3bd2-5c08-a506-8afc8e1d3e0e.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PANGIF-14A (bone marrow normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 353 have no estimate.
https://portal.gdc.cancer.gov/files/d0717312-f4fa-4f4a-896f-45f1ff08aa0d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 526; copy number 1: 131; copy number 2: 57,497; copy number 3: 2,083; copy number 4: 25; copy number 5: 8.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:55,673,536–55,686,160, 3 genes (within-gene range 0–2): OR4V1P, OR4P1P, AP006437.1.
- chr19:43,192,702–43,269,530, 3 genes (within-gene range 0–2): PSG4, CEACAMP10, PSG9.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:187,706,561–187,714,735, 2 genes, copy number 5: SLC4A1APP2, AL645474.1.
- chr12:7,856,169–7,936,187, 6 genes, copy number 5: Metazoa_SRP, AC006517.1, AC124891.1, NANOGP1, AC007536.1, SLC2A3.

Autosomal genes at a single copy (total copy number 1): 131. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
